Somatic mutation profile of tumor specimen TCGA-41-2575-01A (aliquot TCGA-41-2575-01A-01D-1495-08) from TCGA case TCGA-41-2575, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.5 years (27,587 days).
Specimen TCGA-41-2575-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5ed4d0e-dd93-4225-995b-72912ea8ebdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-41-2575-10A (Blood Derived Normal), aliquot TCGA-41-2575-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/322b687e-d4fa-4487-b59e-463c87d336f4

The open-access MAF lists 65 somatic variants for this specimen: 49 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 12, Nonsense Mutation 3, Intron 2, RNA 2, Splice Region 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-1G>C p.X225_splice | Splice Site (SNP) | VAF 47/83 reads (57%) | hotspot (GDC flag); catalogued as CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; called by muse, mutect2, varscan2
- ADAMTS7 | c.2731G>A p.V911M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as rs565586720, COSV66307465; called by muse, varscan2
- AJUBA | c.1256G>A p.G419E | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV52986938; called by muse, mutect2, varscan2
- BOC | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs772475137, COSV56347972; called by muse, mutect2, varscan2
- BPTF | c.2381A>T p.Q794L | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58848510; called by muse, mutect2, varscan2
- CASR | c.1315C>A p.P439T | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV56141985; called by muse, mutect2, varscan2
- CFAP52 | c.1750G>T p.V584L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV53307604; called by muse, mutect2, varscan2
- DNAH8 | c.3717C>A p.A1239= | Splice Region (SNP) | VAF 31/90 reads (34%) | catalogued as COSV59484921; called by muse, mutect2, varscan2
- DNAJC10 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 92/230 reads (40%) | catalogued as rs980369401, COSV51148604, COSV99899513; called by muse, mutect2, varscan2
- EIF2S3 | c.177A>T p.K59N | Missense Mutation (SNP) | VAF 69/82 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53408464; called by muse, mutect2, varscan2
- FAM13C | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53257008; called by muse, mutect2, varscan2
- FBLN2 | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369694803; called by muse, mutect2, varscan2
- FHL3 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65952921; called by muse, mutect2, varscan2
- FLG | c.4828C>T p.R1610W | Missense Mutation (SNP) | VAF 177/364 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs560805546, COSV64238918; called by muse, mutect2, varscan2
- FOXD4L5 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); catalogued as rs779479997, COSV66241365; called by muse, mutect2, varscan2
- GRHL2 | c.1493A>G p.Y498C | Missense Mutation (SNP) | VAF 123/244 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV52555984; called by muse, mutect2, varscan2
- KCNH5 | c.1521T>A p.D507E | Missense Mutation (SNP) | VAF 76/121 reads (63%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV59780583; called by muse, mutect2, varscan2
- KCNU1 | c.2247G>T p.K749N | Missense Mutation (SNP) | VAF 108/367 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV67760308; called by muse, mutect2, varscan2
- KMT2B | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 109/274 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52892143, COSV52892749; called by muse, mutect2, varscan2
- LRRCC1 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV64483307, COSV64486246; called by muse, mutect2, varscan2
- MOB4 | c.533T>C p.F178S | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52097429; called by muse, mutect2, varscan2
- MRPL32 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 55/219 reads (25%) | catalogued as rs764122226, COSV56239135; called by muse, mutect2, varscan2
- MYO1G | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.193); catalogued as COSV51857415; called by muse, mutect2, varscan2
- NCAPG | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 57/354 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as rs764421049, COSV52273120; called by muse, mutect2, varscan2
- OR5AK2 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58805520; called by muse, mutect2, varscan2
- PC | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.774); catalogued as COSV58994691; called by muse, mutect2, varscan2
- PCDHGA3 | c.702T>G p.D234E | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54048244; called by muse, mutect2, varscan2
- PRAMEF12 | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.211); catalogued as COSV63216847; called by muse, mutect2, varscan2
- PXDNL | c.1580A>C p.N527T | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.82); PolyPhen benign (0.017); catalogued as rs777817408, COSV62500315; called by muse, mutect2, varscan2
- RNF130 | c.1207A>C p.M403L | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV56154432; called by muse, mutect2, varscan2
- RPF1 | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65706109; called by muse, mutect2, varscan2
- RYR2 | c.5740T>C p.C1914R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63719003; called by muse, mutect2
- SCN3A | c.2108A>G p.Q703R | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as rs1206384329, COSV51826788; called by muse, mutect2, varscan2
- SEMG1 | c.1036A>G p.I346V | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV54874902; called by muse, mutect2
- SERPINB3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 141/244 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs140650845, COSV52194780; called by muse, mutect2, varscan2
- SLC38A4 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750931344, COSV56971942; called by muse, mutect2, varscan2
- THSD7B | c.4631G>T p.G1544V (on ENST00000272643; = p.G1542V on NM_001316349.2) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55745059; called by muse, mutect2, varscan2
- TMEM205 | c.283A>C p.S95R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV55793216; called by muse, mutect2, varscan2
- TMEM214 | c.1981A>T p.S661C | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.807); catalogued as COSV53194267; called by muse, mutect2, varscan2
- TNFRSF10A | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.945); catalogued as COSV99646122; called by muse, mutect2
- TRIM7 | c.1013A>T p.K338I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as COSV51253051; called by muse, mutect2, varscan2
- UBASH3A | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as COSV52316714; called by muse, mutect2, varscan2
- UBXN2B | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 119/268 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1271327769, COSV68309923; called by muse, mutect2, varscan2
- YBX2 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50302781; called by muse, mutect2, varscan2
- YWHAE | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 48/127 reads (38%) | catalogued as COSV51985750; called by muse, mutect2, varscan2
- ZCWPW1 | c.127G>T p.G43W | Missense Mutation (SNP) | VAF 77/174 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61250756; called by muse, mutect2, varscan2
- ZDBF2 | c.5564T>G p.F1855C | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65630680; called by muse, mutect2, varscan2
- ZIM3 | c.1115T>A p.F372Y | Missense Mutation (SNP) | VAF 104/162 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54147280; called by muse, mutect2, varscan2
- PCDH9 | c.294_295del p.A99Wfs*6 | Frame Shift Del (DEL) | VAF 33/104 reads (32%) | called by pindel, varscan2
- ABCA6 | c.4656C>T p.D1552= | Silent (SNP) | VAF 105/251 reads (42%) | catalogued as rs769359582, COSV52637693; called by muse, mutect2, varscan2
- ADAMTS17 | c.2448C>T p.C816= | Silent (SNP) | VAF 119/290 reads (41%) | catalogued as rs146325180; called by muse, mutect2, varscan2
- CDCP2 | c.810C>T p.S270= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as COSV61286368; called by muse, mutect2, varscan2
- CSH2 | c.87C>T p.T29= | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as rs753371030, COSV61081035, COSV61081240; called by muse, mutect2, varscan2
- FARP1 | c.1545G>A p.P515= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs781763638, COSV60350037; called by muse, mutect2, varscan2
- FETUB | c.516C>T p.T172= | Silent (SNP) | VAF 59/267 reads (22%) | catalogued as rs267599724, COSV54007432; called by muse, mutect2, varscan2
- FZD1 | c.957G>A p.S319= | Silent (SNP) | VAF 53/179 reads (30%) | catalogued as COSV55313725; called by muse, mutect2, varscan2
- LILRA4 | c.1218G>C p.L406= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as rs200134720, COSV52495383; called by muse, mutect2, varscan2
- PLCL1 | c.2091G>A p.P697= | Silent (SNP) | VAF 130/317 reads (41%) | catalogued as rs147854527, COSV70882044; called by muse, mutect2, varscan2
- PLEC | c.7974G>A p.Q2658= (on ENST00000322810 / NM_201380.4; = p.Q2548= on NM_000445.5) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV59702933; called by muse, mutect2, varscan2
- RNH1 | c.1368C>T p.S456= | Silent (SNP) | VAF 88/204 reads (43%) | catalogued as COSV57280256; called by muse, mutect2, varscan2
- VAV1 | c.1113C>T p.N371= | Silent (SNP) | VAF 155/398 reads (39%) | catalogued as COSV58386570; called by muse, mutect2, varscan2
- AC073310.1 | n.362T>A | RNA (SNP) | VAF 113/358 reads (32%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.102A>G | RNA (SNP) | VAF 16/53 reads (30%) | catalogued as rs1468042849; called by muse, mutect2, varscan2
- LNX1 | c.380+15698C>T | Intron (SNP) | VAF 286/1543 reads (19%) | catalogued as COSV99819774; called by muse, mutect2, varscan2
- TTN | c.10361-3701G>T | Intron (SNP) | VAF 57/144 reads (40%) | catalogued as COSV60392400; called by muse, mutect2, varscan2
